Surgical pathology report (de-identified scan), TCGA case TCGA-06-0150, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0150-01A (Primary Tumor).

Patient Name: [REDACTED]

Sex: Male Room/Bed:

PATIENT NAME:

P. NO. [REDACTED]

C. ERING PHYSICIAN:

AGE/SEX:

M

ACC. NO. [REDACTED]

PATH. NO. [REDACTED]

MED. REC. NO. [REDACTED]

NAME: [REDACTED]

AGE/SEX: M

PHYSICIAN:

SURGERY DATE:

RECEIVE DATE:

PATHOLOGICAL DIAGNOSIS:BRAIN BIOPSY: GLIOBLASTOMA (PROLIFERATIVE INDEX, MIB-1: MORE THAN 40%).

Operation/Specimen: Brain tumor. F.S.

Clinical History and Pre-Op Dx: None given.

GROSS PATHOLOGY: The specimen is labeled brain biopsy consisting of 0.2 x 0.4 cm pink-white tissue. A portion of the specimen has been examined by frozen section and is submitted in cassette 1. The remaining tissue is submitted in cassette 2.

INTRAOPERATIVE CONSULTATION: Frozen section diagnosis: High grade glioma.

MICROSCOPIC: Sections show a glioblastoma characterized by high cellular density, frequent nuclear pleomorphism, mitotic figures, endothelial-vascular proliferation with thrombosis and patchy necrosis. The astrocytic lineage of the tumor cells is confirmed by positive GFAP stain. The proliferative index as measured by MIB-1 stain is more than 40%.

TISSUE COMMITTEE CODE:
BILLING CODES

Source: NCI Genomic Data Commons file 44628e87-879d-49d1-b753-8436985d0f0e (TCGA-06-0150.4854A37F-5F68-4EA0-99F7-E0572EA9533F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).